Gene-level copy-number profile of specimen HCM-BROD-0791-C43-85O from HCMI case HCM-BROD-0791-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 61.0 years (22,298 days).
Specimen HCM-BROD-0791-C43-85O: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 22.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f3afa2be-5280-470f-be7d-b515e13ae8c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0791-C43-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/5d83398c-5e8d-46f7-a4c1-aeda70682c36

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 16; copy number 2: 7,151; copy number 3: 8,013; copy number 4: 41,643; copy number 5: 885; copy number 6: 496; copy number 7: 46; copy number 9: 56; copy number 10: 102; copy number 11: 453; copy number 12: 2; copy number 13: 4; copy number 15: 15; copy number 19: 13; copy number 21: 10.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 655 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:141,887,148–142,272,235, 10 genes, copy number 21: OR9A1P, MGAM, OR9N1P, OR9A4, CLEC5A, TAS2R38, MGAM2, MOXD2P, PRSS58, TRY2P.
- chr17:7,930,345–22,424,731, 520 genes, copy number 10–19 (within-gene range 2–19) (broad region; genes not listed).
- chr19:27,638,483–33,361,448, 119 genes, copy number 9–11 (broad region; genes not listed).
- chr21:8,986,999–9,027,329, 4 genes, copy number 13: MIR3648-2, CR392039.1, CR392039.3, CDRT15P9.
- chr22:18,636,445–18,653,617, 2 genes, copy number 12: CA15P2, PPP1R26P2.

Autosomal genes at a single copy (total copy number 1): 16. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
